Gene-level copy-number profile of tumor specimen TCGA-97-A4M1-01A from TCGA case TCGA-97-A4M1, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.8 years (19,272 days).
Specimen TCGA-97-A4M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.75458cc0-4fe8-43fa-acde-0f0993661a20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-A4M1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1952f1af-a497-449c-b2bf-a9ba533cb355

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 2,341; copy number 2: 17,377; copy number 3: 25,459; copy number 4: 13,421; copy number 5: 702; copy number 6: 338; copy number 7: 52; copy number 8: 8; copy number 9: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-A4M1-01A-11D-A24O-01): tumor purity 0.36, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,858,127–8,963,077, 2 genes: PTPRD-AS1, AL596451.1.
- chr9:87,724,051–89,178,818, 40 genes: CTSL, AL160279.1, CTSL3P, AL772337.4, FBP2P1, ELF2P3, NPAP1P7, CTSLP8, AL772337.2, AL772337.1, AL772337.3, SPATA31E1, SPATA31C1, AL353572.2, AL353572.3, CDK20, RNU6-86P, RPS10P3, AL353572.4, AL353572.1, SPATA31C2, AL353726.1, AL353726.2, AL451142.1, AL451142.2, RPSAP49, AL353748.3, SPIN1, AL353748.2, HNRNPA1P14, AL353748.1, NXNL2, LINC02843, AL390791.1, MIR4289, PCNPP2, AL772202.1, S1PR3, SHC3, AL353150.1.
- chr9:89,312,225–89,312,306, 1 gene: MIR3153.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 134 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–612,210, 24 genes, copy number 9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1.
- chr5:6,765,891–8,457,564, 35 genes, copy number 7 (within-gene range 4–7): LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4.
- chr5:10,478,037–10,777,062, 17 genes, copy number 7: MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:17,306,381–17,955,857, 39 genes, copy number 9 (within-gene range 5–9): AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223.
- chr5:22,139,247–22,580,819, 4 genes, copy number 8: AC139497.1, PMCHL1, AC138854.1, GCNT1P2.
- chr7:151,375,909–151,879,223, 11 genes, copy number 9: WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1.
- chr9:101,569,352–102,055,741, 4 genes, copy number 8 (within-gene range 2–8): GRIN3A, PPP3R2, MTND3P4, ARL2BPP7.

Autosomal genes at a single copy (total copy number 1): 2,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
